Surgical pathology report (de-identified scan), TCGA case TCGA-61-1904, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1904-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –
PAPILLARY SEROUS CARCINOMA.

PART 2: OMENTUM, OMENTECTOMY –
PAPILLARY SEROUS CARCINOMA.

PART 3: UTERUS AND CERVIX WITH BILATERAL TUBES AND OVARIES AND RECTO-SIGMOID COLON, TOTAL ABDOMINAL HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY, AND RECTO-SIGMOID COLECTOMY –

- A. POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA INVOLVING RIGHT AND LEFT OVARIES.
- B. LEFT OVARIAN MASS MEASURES 5.0 CM.
- C. RIGHT OVARY MEASURES 3.0 CM.
- D. OVARIAN SURFACE INVOLVEMENT IS IDENTIFIED.
- E. NO DEFINITIVE LYMPHOVASCULAR INVASION IS IDENTIFIED.
- F. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYSTS AND PAPILLARY SEROUS CARCINOMA INVOLVING PARATUBAL SOFT TISSUE.
- G. CERVIX, UNREMARKABLE.
- H. INACTIVE ENDOMETRIUM.
- I. MYOMETRIUM, UNREMARKABLE.
- J. LEIOMYOMA WITH FOCI OF ENDOMETRIOSIS (5.0 CM).
- K. COLON, UNREMARKABLE.

PART 4: LEFT EXTERNAL ILIAC LYMPH NODE, BIOPSY –
TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 5: LEFT OBTURATOR LYMPH NODE, BIOPSY –

- A. FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- B. NO LYMPHOID TISSUE SEEN.

PART 6: LEFT COMMON ILIAC LYMPH NODE, BIOPSY –
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 7: LEFT PERIAORTIC LYMPH NODES, BIOPSY –
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 8: RIGHT EXTERNAL ILIAC LYMPH NODES, BIOPSY –
THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 9: RIGHT OBTURATOR LYMPH NODE, BIOPSY –
NEGATIVE FOR TUMOR (0/1).

PART 10: RIGHT PERIAORTIC LYMPH NODES, BIOPSY –
TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 11: RIGHT COMMON ILIAC LYMPH NODES, BIOPSY –
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 5.0 cm
TUMOR TYPE:	Papillary serous carcinoma
VASCULAR INVASION:	No
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Fallopian Tubes, Omentum
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 11
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC

Source: NCI Genomic Data Commons file 57435213-fb8d-499c-b429-178667e28d3f (TCGA-61-1904.F2276820-0D2E-45AF-88AD-33DB5A563A40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).